Gene-level copy-number profile of tumor specimen TCGA-2G-AAHK-01A from TCGA case TCGA-2G-AAHK, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 39.0 years (14,255 days).
Specimen TCGA-2G-AAHK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b34dd5cf-db59-498c-bd69-6860a36a960a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAHK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/facad6bf-fd0e-49a5-a0a2-d103f675aa5f

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 55; copy number 2: 1,877; copy number 3: 4,810; copy number 4: 17,911; copy number 5: 3,672; copy number 6: 20,507; copy number 7: 3,627; copy number 8: 3,505; copy number 9: 962; copy number 10: 1,033; copy number 11: 122; copy number 12: 19; copy number 13: 19; copy number 14: 71; copy number 15: 68; copy number 16: 105; copy number 17: 297; copy number 18: 37; copy number 19: 211.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:57,204,379–57,204,799, 1 gene: MTCO2P3.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 808 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:674,801–33,576,200, 799 genes, copy number 13–19 (broad region; genes not listed).
- chr14:18,333,726–18,419,273, 4 genes, copy number 16: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr22:15,282,557–15,350,043, 5 genes, copy number 16: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2.

Autosomal genes at a single copy (total copy number 1): 55. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
